Somatic mutation profile of tumor specimen TCGA-B4-5838-01A (aliquot TCGA-B4-5838-01A-11D-1669-08) from TCGA case TCGA-B4-5838, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2; Age at diagnosis: 52.7 years (19,242 days).
Specimen TCGA-B4-5838-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b795a17f-062a-45fe-a2ec-af0191117e36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5838-10A (Blood Derived Normal), aliquot TCGA-B4-5838-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3cbc02-6ff4-4309-ad69-1000545f4d2c

The open-access MAF lists 66 somatic variants for this specimen: 58 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 46, Silent 8, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.10310G>C p.G3437A | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV57223164, COSV99948812; called by muse, mutect2, varscan2
- ALG13 | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV52642587, COSV99321802; called by muse, mutect2
- ARHGEF17 | c.4252G>C p.D1418H | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55235323; called by muse, mutect2, varscan2
- CELSR1 | c.4770-2A>C p.X1590_splice | Splice Site (SNP) | VAF 27/82 reads (33%) | catalogued as COSV53095564; called by muse, mutect2, varscan2
- CFAP43 | c.147A>G p.I49M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53379862; called by muse, mutect2, varscan2
- CHTF18 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs367945137; called by muse, mutect2
- CUX1 | c.539A>C p.Q180P (on ENST00000292535 / NM_181552.4; = p.Q191P on NM_001913.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52908533; called by muse, mutect2, varscan2
- DXO | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs752195518, COSV61714518; called by muse, mutect2, varscan2
- EFCAB6 | c.3395A>C p.Q1132P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV53068373; called by muse, mutect2, varscan2
- F9 | c.1354A>C p.N452H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV54381704; called by muse, mutect2, varscan2
- FGF10 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV52937508; called by muse, mutect2, varscan2
- FLI1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55642384; called by muse, mutect2
- FLT1 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56735724, COSV99164577; called by muse, mutect2, varscan2
- GAS2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs745338293, COSV53410318; called by muse, mutect2, varscan2
- GPT | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52954145; called by muse, mutect2, varscan2
- HCFC1 | c.2110G>C p.G704R | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV60075281; called by muse, mutect2, varscan2
- HSPA12B | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54768366; called by muse, mutect2, varscan2
- HYDIN | c.9032A>T p.K3011M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59264572; called by mutect2, varscan2
- HYDIN | c.8987G>A p.G2996D | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.118); catalogued as COSV59264603; called by muse, varscan2
- IGKV1D-42 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1342177063; called by muse, mutect2
- IQGAP3 | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63253442; called by muse, mutect2, varscan2
- ITGA7 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57698421; called by muse, mutect2, varscan2
- LAMA3 | c.5354A>G p.Q1785R (on ENST00000313654 / NM_198129.4; = p.Q176R on NM_000227.6) | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs947043432, COSV52539378; called by muse, mutect2, varscan2
- LRIG2 | c.2735A>T p.Y912F | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63163247; called by muse, mutect2, varscan2
- MGAT4A | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.952); catalogued as rs770106129, COSV53849135; called by muse, mutect2, varscan2
- NSD1 | c.4871C>A p.P1624Q | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61780515; called by muse, mutect2, varscan2
- NUP153 | c.87C>G p.Y29* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV50456815; called by muse, mutect2, varscan2
- OR6F1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV57468754; called by muse, mutect2, varscan2
- PAXBP1 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.241); catalogued as COSV51611099; called by muse, varscan2
- PCDHGA12 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV52760332; called by muse, mutect2, varscan2
- PI4KB | c.637G>A p.A213T (on ENST00000368873 / NM_001369623.1; = p.A225T on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV55019883; called by muse, mutect2, varscan2
- PNMA1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1462148807, COSV54097164; called by muse, mutect2, varscan2
- RAI14 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs202167881; called by muse, mutect2, varscan2
- RARS1 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51565154; called by muse, mutect2, varscan2
- RPL21 | c.89A>T p.Y30F | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV55388987; called by muse, mutect2, varscan2
- SEC14L5 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as rs1280393457, COSV52040355; called by muse, mutect2, varscan2
- SLC12A2 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52474345; called by muse, mutect2, varscan2
- SP140L | c.42C>G p.N14K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.983); catalogued as COSV54746306; called by muse, mutect2, varscan2
- SRRT | c.2326A>G p.I776V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV53819968; called by muse, mutect2, varscan2
- TAC3 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as COSV55648577; called by muse, mutect2, varscan2
- TKT | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56246343; called by muse, mutect2, varscan2
- TMEM39A | c.995T>G p.M332R | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59901106; called by muse, mutect2, varscan2
- TMPRSS13 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.202); catalogued as COSV70627094; called by muse, mutect2
- TRAF6 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.069); catalogued as rs746111041, COSV61922487; called by muse, mutect2, varscan2
- TSTD2 | c.1151T>A p.I384N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52250519; called by muse, mutect2, varscan2
- UBXN4 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55636540; called by muse, mutect2, varscan2
- XPO7 | c.1662T>G p.F554L | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV53017894; called by muse, mutect2, varscan2
- ZNF202 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60246811, COSV60247861; called by muse, mutect2, varscan2
- ZNF563 | c.1429T>G p.*477Gext*2 | Nonstop Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV53371437; called by muse, mutect2, varscan2
- ZNRF4 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV55775586; called by muse, mutect2, varscan2
- AQP1 | c.23_28del p.K8_F10delinsI | In Frame Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- CLEC17A | c.163_164insTT p.S55Ffs*66 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- DUSP1 | c.386del p.S129Wfs*21 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- LIMS2 | c.677_683del p.K226Rfs*36 (on ENST00000355119 / NM_001161403.3; = p.K250Rfs*36 on NM_017980.4) | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- MCM9 | c.105del p.D35Efs*11 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- PRR12 | c.2492del p.N831Mfs*8 (on ENST00000615927; = p.N1652Mfs*8 on NM_020719.3) | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | called by mutect2, pindel, varscan2
- RIOK3 | c.306dup p.F103Ifs*5 | Frame Shift Ins (INS) | VAF 26/87 reads (30%) | called by mutect2, varscan2
- SYNJ1 | c.3711del p.P1238Lfs*21 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel
- DCST2 | c.546G>A p.R182= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55053400; called by mutect2, varscan2
- HMMR | c.1563A>G p.L521= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV62374351; called by muse, mutect2, varscan2
- OR11H4 | c.810A>T p.V270= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as COSV59560662; called by muse, mutect2, varscan2
- POMT1 | c.660C>G p.V220= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV61227127, COSV61227953; called by muse, mutect2, varscan2
- QRICH2 | c.3621C>T p.I1207= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1374481190, COSV53155845; called by muse, mutect2
- RBM28 | c.1287G>A p.T429= | Silent (SNP) | VAF 88/333 reads (26%) | catalogued as rs775217521, COSV56162591, COSV99775444; called by muse, mutect2, varscan2
- TJP1 | c.1443A>G p.E481= | Silent (SNP) | VAF 11/180 reads (6%) | catalogued as rs1361315565, COSV62044296; called by muse, mutect2
- TSTD2 | c.534C>T p.D178= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV57847023; called by muse, mutect2
